Somatic mutation profile of tumor specimen C3N-02256-01 (aliquot CPT0182580006) from CPTAC case C3N-02256, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 65.1 years (23,761 days).
Specimen C3N-02256-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 042c5ae5-0d9d-4cbc-950b-d73cef395442.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02256-31 (Blood Derived Normal), aliquot CPT0182600002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98efb2f3-4a19-412b-864c-3b0134c8f586

The open-access MAF lists 77 somatic variants for this specimen: 51 protein-altering or splice-affecting, 12 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 12, Intron 9, Nonsense Mutation 3, Frame Shift Del 2, 3'Flank 2, 3'UTR 1, In Frame Ins 1, Splice Site 1, In Frame Del 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.278A>G p.H93R | Missense Mutation (SNP) | VAF 123/193 reads (64%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs121909238, CM051214, COSV100910602, COSV64296545, COSV64296755; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 542/648 reads (84%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AGAP1 | c.2138G>A p.R713H (on ENST00000304032 / NM_001037131.3; = p.R660H on NM_014914.5) | Missense Mutation (SNP) | VAF 69/182 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as rs766895412, COSV58334446; called by muse, mutect2, varscan2
- ANKRD18A | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.293); catalogued as rs1388061883; called by muse, mutect2, varscan2
- CSH1 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 275/735 reads (37%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.985); catalogued as rs1268681042, COSV60243026; called by muse, mutect2, varscan2
- DNAH12 | c.2968C>T p.R990C (on ENST00000351747; = p.R1013C on NM_001366028.2) | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs548750794; called by muse, mutect2, varscan2
- FRK | c.670G>A p.V224M | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.816); catalogued as rs555269385, COSV73384289; called by muse, mutect2, varscan2
- KLF3 | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 74/168 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54711262; called by muse, mutect2, varscan2
- KLHL29 | c.2227C>T p.R743* | Nonsense Mutation (SNP) | VAF 59/127 reads (46%) | catalogued as rs1477760310, COSV101517097; called by muse, mutect2, varscan2
- LRRIQ4 | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 116/327 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.939); catalogued as rs767133220; called by muse, mutect2, varscan2
- NEFM | c.1970C>T p.P657L | Missense Mutation (SNP) | VAF 506/605 reads (84%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1485845866, COSV55334284; called by muse, mutect2, varscan2
- NUP88 | c.1616G>A p.R539H | Missense Mutation (SNP) | VAF 95/114 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs755596505; called by muse, mutect2, varscan2
- PRSS41 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 163/478 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as rs749624258; called by muse, mutect2, varscan2
- RALGAPA1 | c.4030G>A p.V1344I | Missense Mutation (SNP) | VAF 92/278 reads (33%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs1270351818; called by muse, mutect2, varscan2
- SCNN1G | c.53C>T p.T18M | Missense Mutation (SNP) | VAF 163/425 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.609); catalogued as COSV55601162; called by muse, mutect2, varscan2
- SP100 | c.1123C>T p.R375* | Nonsense Mutation (SNP) | VAF 68/192 reads (35%) | catalogued as rs1335638714; called by muse, mutect2, varscan2
- TRIML2 | c.192G>T p.K64N | Missense Mutation (SNP) | VAF 74/157 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.331); catalogued as rs529693724, COSV100455889; called by muse, mutect2, varscan2
- TRPC5 | c.1601G>A p.G534E | Missense Mutation (SNP) | VAF 120/301 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53285708; called by muse, mutect2, varscan2
- TSNAXIP1 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 63/153 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs779409740, COSV54649425; called by muse, mutect2, varscan2
- VWA8 | c.2404C>T p.R802* | Nonsense Mutation (SNP) | VAF 96/230 reads (42%) | catalogued as rs368033977, COSV55700275; called by muse, mutect2, varscan2
- ADAMTS1 | c.1231C>T p.H411Y | Missense Mutation (SNP) | VAF 81/176 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADCK5 | c.1226_1228del p.D409del | In Frame Del (DEL) | VAF 38/52 reads (73%) | called by pindel, varscan2
- ADGRG6 | c.3560G>T p.R1187M | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AHNAK2 | c.5349G>T p.E1783D | Missense Mutation (SNP) | VAF 286/737 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, varscan2
- BOD1L1 | c.5609T>A p.V1870D | Missense Mutation (SNP) | VAF 89/206 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- CCDC168 | c.12450T>A p.D4150E | Missense Mutation (SNP) | VAF 67/157 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CDKN2C | c.224A>G p.H75R | Missense Mutation (SNP) | VAF 130/294 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DCAF12L1 | c.1302C>A p.H434Q | Missense Mutation (SNP) | VAF 74/213 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DGKK | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 82/214 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- DSC1 | c.1685C>T p.T562I | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DZANK1 | c.1690G>C p.G564R (on ENST00000262547 / NM_001099407.1; = p.G371R on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 171/381 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- EZHIP | c.542C>A p.P181H | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- FBN2 | c.3386G>T p.G1129V | Missense Mutation (SNP) | VAF 211/573 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FREM2 | c.238del p.R80Gfs*31 | Frame Shift Del (DEL) | VAF 24/106 reads (23%) | called by pindel, varscan2
- HLA-A | c.780del p.D262Mfs*35 | Frame Shift Del (DEL) | VAF 61/361 reads (17%) | called by mutect2, pindel, varscan2
- LCP1 | c.919G>C p.A307P | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- LRRIQ1 | c.3454A>T p.T1152S | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MEP1A | c.1817C>A p.T606N | Missense Mutation (SNP) | VAF 116/303 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- MGAM2 | c.3925-2A>G p.X1309_splice | Splice Site (SNP) | VAF 57/290 reads (20%) | called by muse, mutect2, varscan2
- NBAS | c.4461G>T p.E1487D | Missense Mutation (SNP) | VAF 62/219 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- NEXMIF | c.2513C>T p.P838L | Missense Mutation (SNP) | VAF 247/277 reads (89%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR13F1 | c.587A>T p.Q196L | Missense Mutation (SNP) | VAF 56/162 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- PCLO | c.9077C>T p.T3026I | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SETD2 | c.7002_7004dup p.Q2335dup | In Frame Ins (INS) | VAF 63/212 reads (30%) | called by mutect2, pindel, varscan2
- SFPQ | c.766C>T p.H256Y | Missense Mutation (SNP) | VAF 18/259 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.029); called by muse, mutect2
- SLC25A40 | c.294G>T p.E98D | Missense Mutation (SNP) | VAF 49/290 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TIAM2 | c.535A>G p.N179D | Missense Mutation (SNP) | VAF 149/347 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- TTN | c.950C>T p.P317L | Missense Mutation (SNP) | VAF 75/219 reads (34%) | PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- USP30 | c.569A>G p.H190R | Missense Mutation (SNP) | VAF 74/192 reads (39%) | SIFT tolerated (0.58); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- VAPA | c.724T>C p.F242L (on ENST00000400000 / NM_194434.3; = p.F287L on NM_003574.6) | Missense Mutation (SNP) | VAF 63/144 reads (44%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- ZNF676 | c.934C>A p.P312T (on ENST00000650058; = p.P280T on NM_001001411.3) | Missense Mutation (SNP) | VAF 105/321 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- DCAF8L1 | c.1626G>A p.S542= | Silent (SNP) | VAF 79/91 reads (87%) | catalogued as rs1391268224, COSV71595550; called by muse, mutect2, varscan2
- ELFN1 | c.519C>T p.S173= | Silent (SNP) | VAF 139/644 reads (22%) | catalogued as rs1047130418; called by muse, mutect2, varscan2
- FRG2C | c.141C>A p.A47= | Silent (SNP) | VAF 139/967 reads (14%) | called by mutect2, varscan2
- KCNC2 | c.606C>T p.D202= | Silent (SNP) | VAF 132/305 reads (43%) | catalogued as rs199945851, COSV54382284; called by muse, mutect2, varscan2
- LOXHD1 | c.1302C>T p.T434= | Silent (SNP) | VAF 113/295 reads (38%) | catalogued as rs377086603, COSV100191011; called by muse, mutect2, varscan2
- NYAP2 | c.117G>A p.A39= | Silent (SNP) | VAF 116/300 reads (39%) | catalogued as rs916212363, COSV56014602; called by muse, mutect2, varscan2
- PDGFB | c.282C>T p.I94= | Silent (SNP) | VAF 141/311 reads (45%) | catalogued as rs748350476, COSV58649940; called by muse, mutect2, varscan2
- ROS1 | c.3702T>A p.I1234= | Silent (SNP) | VAF 59/171 reads (35%) | called by muse, mutect2, varscan2
- SMURF1 | c.672C>T p.P224= | Silent (SNP) | VAF 21/124 reads (17%) | called by muse, mutect2
- TCAF2 | c.1089C>G p.A363= | Silent (SNP) | VAF 25/192 reads (13%) | called by mutect2, varscan2
- VSIG2 | c.714C>T p.S238= | Silent (SNP) | VAF 51/126 reads (40%) | called by muse, mutect2, varscan2
- ZNF735 | c.657C>T p.G219= | Silent (SNP) | VAF 64/311 reads (21%) | called by muse, mutect2, varscan2
- AL512625.1 | n.387G>A | RNA (SNP) | VAF 33/272 reads (12%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1039-4043G>A | Intron (SNP) | VAF 6/36 reads (17%) | catalogued as rs782152145, COSV61449103; called by muse, varscan2
- ATR | c.7193-11C>T | Intron (SNP) | VAF 90/239 reads (38%) | called by muse, varscan2
- CNGA3 | c.215+382C>T | Intron (SNP) | VAF 103/273 reads (38%) | called by muse, mutect2, varscan2
- COL1A1 | c.333+39G>A | Intron (SNP) | VAF 264/327 reads (81%) | called by muse, mutect2, varscan2
- DUOXA1 | chr15:45117561 A>G | 3'Flank (SNP) | VAF 112/304 reads (37%) | called by muse, mutect2, varscan2
- FAM153CP | n.201-2375T>C | Intron (SNP) | VAF 111/257 reads (43%) | catalogued as rs1561591300; called by muse, mutect2, varscan2
- FBN1 | c.-40C>T | 5'UTR (SNP) | VAF 124/280 reads (44%) | called by muse, mutect2, varscan2
- KNCN | c.*14C>T | 3'UTR (SNP) | VAF 18/41 reads (44%) | catalogued as rs1443210819; called by muse, mutect2, varscan2
- LRRFIP1 | c.249+12987G>T | Intron (SNP) | VAF 114/310 reads (37%) | called by muse, mutect2, varscan2
- NOTCH4 | c.1861+64G>T | Intron (SNP) | VAF 107/220 reads (49%) | called by muse, varscan2
- RPL37AP1 | chr20:44462240 G>A | 3'Flank (SNP) | VAF 48/80 reads (60%) | catalogued as rs775615096; called by muse, mutect2, varscan2
- TEX30 | c.16-9G>A | Intron (SNP) | VAF 14/52 reads (27%) | called by muse, mutect2, varscan2
- VSIG1 | c.213+3291C>T | Intron (SNP) | VAF 65/206 reads (32%) | catalogued as rs768992380, COSV54258812; called by muse, mutect2, varscan2
